Gene-level copy-number profile of tumor specimen TCGA-09-1665-01B from TCGA case TCGA-09-1665, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 73.9 years (27,010 days).
Specimen TCGA-09-1665-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7fa92667-c84b-4b05-ab4f-4813e5a2e956.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1665-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d55765c-b491-46ed-9e10-a1bf72393690

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 9,596; copy number 2: 22,772; copy number 3: 18,487; copy number 4: 6,595; copy number 5: 1,641; copy number 6: 111; copy number 7: 285; copy number 8: 248; copy number 9: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-1665-01): tumor purity 0.88, ploidy 2.58, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.
- chr5:68,792,609–69,030,165, 6 genes: AC093523.1, VWA8P1, U8, AC093248.1, RN7SKP251, LINC02198.
- chr7:27,412,164–27,412,891, 1 gene: AC004009.2.
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.
- chr10:75,409,142–76,560,168, 12 genes (within-gene range 0–2): AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,332 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:112,621,809–113,209,396, 23 genes, copy number 5: AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1.
- chr3:35,638,945–43,106,079, 171 genes, copy number 5–7 (broad region; genes not listed).
- chr3:61,561,569–65,193,509, 45 genes, copy number 5: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040.
- chr3:65,359,268–65,359,717, 1 gene, copy number 5: AC121493.1.
- chr5:58,198–16,941,951, 295 genes, copy number 8–9 (broad region; genes not listed).
- chr6:124,644,434–127,213,609, 24 genes, copy number 5 (within-gene range 3–5): RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1.
- chr6:145,296,545–149,245,554, 47 genes, copy number 5: AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH, GRM1, FUNDC2P3, RNA5SP222, AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P, KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1, STXBP5, AL355365.1, YAP1P1, SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1.
- chr6:149,243,299–149,291,646, 3 genes, copy number 5: TAB2-AS1, AL031056.2, RN7SL234P.
- chr7:128,207,872–128,410,252, 8 genes, copy number 5: MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1.
- chr7:136,685,559–137,182,107, 1 gene, copy number 5 (within-gene range 3–5): AC009264.1.
- chr7:136,868,669–141,702,166, 97 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:48,710,789–56,917,190, 114 genes, copy number 5 (broad region; genes not listed).
- chr8:110,555,408–112,148,825, 14 genes, copy number 5: AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr8:124,306,189–145,066,685, 387 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:5,765,223–5,842,132, 1 gene, copy number 6 (within-gene range 4–6): GDI2.
- chr10:5,813,985–6,117,457, 11 genes, copy number 6: AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1, RPL32P23, RBM17.
- chr10:6,149,623–6,152,277, 3 genes, copy number 6: RN7SKP78, MIR3155A, MIR3155B.
- chr11:102,520,508–102,625,332, 2 genes, copy number 5 (within-gene range 3–5): MMP7, MMP20.
- chr12:20,368,537–22,690,665, 40 genes, copy number 5–6 (within-gene range 4–6): PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:22,722,229–22,743,091, 2 genes, copy number 6: RPS27P22, AC084819.1.
- chr12:24,642,687–27,710,803, 72 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:27,935,523–28,978,685, 13 genes, copy number 5: AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1.
- chr12:34,149,839–41,072,415, 47 genes, copy number 5 (within-gene range 4–5): AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1.
- chr12:43,353,866–48,191,207, 103 genes, copy number 5–6 (broad region; genes not listed).
- chr15:98,648,539–98,964,530, 1 gene, copy number 5 (within-gene range 4–5): IGF1R.
- chr15:98,784,426–101,933,350, 91 genes, copy number 5 (broad region; genes not listed).
- chr17:45,506,741–57,684,689, 336 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:3,686,970–5,611,006, 58 genes, copy number 5: SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1.
- chr20:32,170,390–34,112,243, 64 genes, copy number 5 (broad region; genes not listed).
- chr20:55,997,357–64,313,132, 258 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
